Somatic mutation profile of tumor specimen ALCH-B2TZ-TTP1-A (aliquot ALCH-B2TZ-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,181 days).
Specimen ALCH-B2TZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7b6c329-38ba-4448-b01c-a7c6b3d06b98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TZ-NB1-A (Blood Derived Normal), aliquot ALCH-B2TZ-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39e8d9e0-e21b-4f7b-9b96-d4cfcd1e524f

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Intron 4, RNA 3, Splice Site 2, 5'UTR 2, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 38/470 reads (8%) | catalogued as rs567573386, CM114528, COSV55325564; ClinVar: likely pathogenic; called by muse, mutect2
- ADARB2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs746581733, COSV67182707; called by muse, mutect2
- ASPM | c.6458A>G p.Y2153C | Missense Mutation (SNP) | VAF 34/537 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV54137073; called by muse, mutect2
- ATR | c.3450+1G>T p.X1150_splice | Splice Site (SNP) | VAF 21/246 reads (9%) | catalogued as COSV100638817; called by muse, mutect2
- CFAP251 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs1009391223; called by muse, mutect2
- FBXL7 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1286536913, COSV61642752; called by muse, mutect2, varscan2
- HACE1 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99493784; called by muse, mutect2
- LPO | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs763969451; called by muse, mutect2
- MGST2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs141597730; called by muse, mutect2
- MUC16 | c.34562C>A p.A11521D | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV67475463; called by muse, mutect2
- NOL4 | c.1696C>A p.L566I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52347405; called by muse, mutect2
- SCRIB | c.4493G>A p.R1498H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427348794, COSV100252372; called by muse, mutect2
- TBK1 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV59158627; called by muse, mutect2
- TMC3 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1260649807, COSV63923156; called by muse, mutect2, varscan2
- TSSK1B | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs772486035, COSV66814933; called by muse, mutect2
- UNC80 | c.9285C>A p.S3095R | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs903923892; called by muse, mutect2, varscan2
- AC026316.4 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 11/342 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.05); called by muse, mutect2
- ADGRA3 | c.3634G>T p.G1212C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.319); called by mutect2, varscan2
- ARMC2 | c.2124T>A p.D708E | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.028); called by muse, mutect2
- ATP13A4 | c.1523+1G>A p.X508_splice | Splice Site (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- BCAR1 | c.2522C>G p.S841C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2
- CAP2 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2
- CUL2 | c.637A>T p.T213S | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCDC1 | c.1628T>G p.I543S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2
- DPYS | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESYT2 | c.887T>G p.I296S (on ENST00000613624; = p.I220S on NM_020728.3) | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GABRA6 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIP1 | c.2921C>T p.P974L (on ENST00000359742 / NM_001379345.1; = p.P922L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.297); called by muse, mutect2
- IGLV2-11 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); called by muse, mutect2
- IL6ST | c.2188G>T p.G730W | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH1 | c.2755G>A p.E919K (on ENST00000271751 / NM_172362.3; = p.E892K on NM_002238.4) | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KRT6C | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 31/452 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2
- KRTAP4-8 | c.54C>G p.D18E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- LIPI | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- MAP3K19 | c.3487T>C p.F1163L | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MLLT3 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- MOSPD2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.146); called by muse, mutect2
- MYLK | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN1 | c.3367G>T p.G1123W | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PCDHA4 | c.1646T>A p.V549E | Missense Mutation (SNP) | VAF 46/513 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLCZ1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PLXNA4 | c.5014A>T p.M1672L | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2
- POP5 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.214); called by muse, mutect2
- PTPRJ | c.2718T>G p.I906M | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2
- SLX4 | c.3818C>T p.T1273I | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- STYXL2 | c.3380A>G p.E1127G | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SYP | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2
- TRAF6 | c.902A>T p.Q301L | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); called by muse, mutect2
- UBR3 | c.3209C>G p.S1070C | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.533); called by muse, mutect2
- USP44 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.199); called by muse, mutect2
- ACVR2A | c.1179C>A p.V393= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- ASB18 | c.102T>C p.D34= | Silent (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- CLEC3A | c.351C>T p.S117= (on ENST00000651443; = p.S108= on NM_005752.6) | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs751293673; called by muse, mutect2, varscan2
- ERGIC3 | c.319C>A p.R107= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- HBEGF | c.405C>T p.H135= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2
- IRX1 | c.1434G>A p.P478= | Silent (SNP) | VAF 18/312 reads (6%) | catalogued as COSV57360112; called by muse, mutect2
- LIM2 | c.117C>T p.H39= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as rs1446502349; called by muse, mutect2
- MVP | c.621G>T p.A207= | Silent (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2
- NAV3 | c.1180C>A p.R394= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV57063271, COSV57075729; called by muse, mutect2
- NPIPB2 | c.477C>T p.T159= (on ENST00000399147; = p.T19= on NM_001355514.1) | Silent (SNP) | VAF 24/436 reads (6%) | catalogued as rs570934217; called by muse, mutect2
- SH3GL2 | c.606C>T p.F202= | Silent (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- ZNF207 | c.1233C>T p.G411= | Silent (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2
- FAM90A27P | n.218C>T | RNA (SNP) | VAF 8/86 reads (9%) | catalogued as rs186427997; called by muse, mutect2, varscan2
- GH1 | c.-28G>A | 5'UTR (SNP) | VAF 32/329 reads (10%) | called by muse, mutect2
- IFT80 | c.777+12210C>G | Intron (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- LMF1 | c.1530-992C>T | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- LY6E | chr8:143018177 C>A | 5'Flank (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- NAMPTP1 | n.712C>T | RNA (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- NR3C1 | c.*3G>A | 3'UTR (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- RPS19BP1 | c.-5C>T | 5'UTR (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- RSPH9 | c.671-4309G>T | Intron (SNP) | VAF 11/93 reads (12%) | catalogued as rs574470769; called by muse, mutect2, varscan2
- UBE2DNL | n.62C>T | RNA (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- VPS50 | c.541-17G>T | Intron (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
